Somatic mutation profile of tumor specimen TCGA-E1-5303-01A (aliquot TCGA-E1-5303-01A-01D-1468-08) from TCGA case TCGA-E1-5303, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 38.9 years (14,212 days).
Specimen TCGA-E1-5303-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70888353-8062-42b2-8c40-6b49ca7b3806.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5303-10A (Blood Derived Normal), aliquot TCGA-E1-5303-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3c117a5-1778-44f5-922b-5d8ff7946cf4

The open-access MAF lists 28 somatic variants for this specimen: 26 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 21, Silent 2, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 50/161 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 66/86 reads (77%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AFP | c.228A>C p.K76N | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV56925945; called by muse, mutect2, varscan2
- AGK | c.242A>C p.E81A | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62595111; called by muse, mutect2, varscan2
- ARID2 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 47/141 reads (33%) | catalogued as COSV57595668; called by muse, mutect2, varscan2
- CEP126 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs567302421, COSV54826947; called by muse, mutect2, varscan2
- CYBC1 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60672776, COSV60673263; called by muse, mutect2, varscan2
- DNAAF5 | c.1967A>G p.D656G | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV52418840; called by muse, mutect2, varscan2
- EMILIN2 | c.3029T>C p.L1010P | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54425273; called by muse, mutect2, varscan2
- FZR1 | c.1126G>C p.G376R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58052473; called by muse, mutect2, varscan2
- KCNV1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs1458883589, COSV52084840; called by muse, mutect2
- MED13L | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56124195; called by muse, mutect2, varscan2
- OR11H4 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.159); catalogued as COSV59560541; called by muse, mutect2
- OR8I2 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 164/491 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs746795179, COSV56168898; called by muse, mutect2, varscan2
- PLA2G4A | c.1973A>G p.E658G | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV66555095; called by muse, mutect2
- SENP7 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 86/500 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs761516159, COSV58614582; called by muse, mutect2, varscan2
- SLC23A3 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55408445; called by muse, mutect2, varscan2
- SPOUT1 | c.1011C>G p.D337E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV63509522; called by muse, mutect2, varscan2
- SPZ1 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs775842332, COSV57064100; called by muse, mutect2, varscan2
- TRIM52 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 112/294 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59844575; called by muse, mutect2, varscan2
- UTRN | c.6835C>T p.R2279C | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs114254210, COSV62340532; called by muse, mutect2, varscan2
- ZFX | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 10/192 reads (5%) | catalogued as COSV58448590; called by muse, mutect2
- ZMAT3 | c.271-1G>C p.X91_splice | Splice Site (SNP) | VAF 45/121 reads (37%) | catalogued as COSV60992276, COSV60994234; called by muse, mutect2, varscan2
- ATRX | c.818dup p.L273Ffs*9 | Frame Shift Ins (INS) | VAF 211/395 reads (53%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2264G>A p.R755H (on ENST00000621492; = p.R721H on NM_025248.3) | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZC3H4 | c.1222_1263del p.D408_K421del | In Frame Del (DEL) | VAF 54/212 reads (25%) | called by mutect2, pindel
- CHD6 | c.6471G>A p.A2157= | Silent (SNP) | VAF 91/278 reads (33%) | catalogued as rs1440547914, COSV64692479; called by muse, mutect2, varscan2
- COG5 | c.945A>G p.G315= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV51756649; called by muse, mutect2
